FM case AD3707 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/5b0c965b-33de-45f3-be0e-b4613018ae48

Male, 51.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); metastasis biopsied or resected from the trachea. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
